MMRF case MMRF_1570 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/70304443-9430-4eda-93a3-02b2b23f22da

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.0 years (19,372 days); ISS stage: I; Days to last known disease status: 980 days (2.7 years); Days to last follow up: 980 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 29 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 110 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days; Days to treatment end: 110 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 155 days; Days to treatment end: 155 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 155 days; Days to treatment end: 155 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 386 days (1.1 years); Days to treatment end: 546 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 546 days (1.5 years); Days to treatment end: 546 days (1.5 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 980.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.913 mg/dL; Immunoglobulin G 15.7 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 1.2 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.45 mmol/L; Albumin 49 g/L; Total Protein 7.4 g/dL; Glucose 4.84 mmol/L.
- Day 64 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.583 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 0.5 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 48 g/L; Total Protein 7.7 g/dL; Glucose 6.99 mmol/L.
- Day 135 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Hemoglobin 6.26 mmol/L; Leukocytes 7.9 ×10⁹/L; Platelets 68 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 1.79 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 6.55 mmol/L.
- Day 252 (ECOG 2): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.595 mg/dL; Immunoglobulin G 9.21 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.14 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 296 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Glucose 4.68 mmol/L.
- Day 372 (ECOG 1): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.63 mg/dL; Immunoglobulin G 9.39 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.55 mmol/L; Albumin 47 g/L; Total Protein 7.4 g/dL; Glucose 5.56 mmol/L.
- Day 442 (ECOG 1): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Hemoglobin 7.44 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 5.5 mmol/L.
- Day 532 (ECOG 1): M Protein 0.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 0.6 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 47 g/L; Total Protein 7.3 g/dL; Glucose 5.17 mmol/L.
- Day 652 (ECOG 1): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.35 mmol/L; Albumin 48 g/L; Total Protein 7.2 g/dL; Glucose 4.18 mmol/L.
- Day 747: M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.53 mg/dL; Hemoglobin 6.76 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 46 g/L; Total Protein 7.1 g/dL; Glucose 4.29 mmol/L.
- Day 810: M Protein 0.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Hemoglobin 7.13 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 0.7 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 48 g/L; Total Protein 7.5 g/dL; Glucose 3.58 mmol/L.

Other clinical attributes
- Day 1: Weight: 68 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1570_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1570_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
